Gene-level copy-number profile of tumor specimen TCGA-06-6391-01A from TCGA case TCGA-06-6391, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.4 years (16,206 days).
Specimen TCGA-06-6391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a7da5da7-e522-420c-bda5-d323582d50bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-6391-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7dc37edd-d31b-4a44-bcdf-17d0ddb7f506

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 231; copy number 2: 51,244; copy number 3: 5,420; copy number 4: 1,133; copy number 5: 765; copy number 6: 537; copy number 7: 223; copy number 8: 37; copy number 9: 213.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-6391-01): tumor purity 0.39, ploidy 2.19, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,029,594, 11 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,775 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,164,008–186,772,986, 193 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:70,972–989,640, 28 genes, copy number 5: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1.
- chr7:1,022,933–1,059,261, 4 genes, copy number 5: MIR339, AC073957.1, GPR146, AC073957.2.
- chr7:7,156,934–8,004,053, 18 genes, copy number 5 (within-gene range 3–5): C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT.
- chr7:7,980,312–7,982,228, 1 gene, copy number 5: AC006042.2.
- chr7:8,938,787–9,615,985, 5 genes, copy number 5–7: AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68.
- chr7:9,634,270–9,635,703, 1 gene, copy number 7: PER3P1.
- chr7:12,211,270–12,403,941, 2 genes, copy number 5 (within-gene range 3–5): TMEM106B, VWDE.
- chr7:15,841,297–15,842,360, 1 gene, copy number 5: AC006041.1.
- chr7:16,208,945–16,270,604, 2 genes, copy number 5 (within-gene range 3–5): RPL36AP29, CRPPA-AS1.
- chr7:23,811,144–34,156,427, 213 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:39,609,610–39,888,664, 14 genes, copy number 5: AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P.
- chr7:54,330,670–54,812,727, 11 genes, copy number 5 (within-gene range 2–5): LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT.
- chr7:55,235,965–56,675,086, 69 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:108,598,352–109,999,624, 12 genes, copy number 5 (within-gene range 3–5): AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8.
- chr7:112,819,147–113,146,330, 6 genes, copy number 6: BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30.
- chr7:117,072,072–117,715,971, 16 genes, copy number 6 (within-gene range 2–6): ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2.
- chr7:127,997,597–128,687,872, 33 genes, copy number 6 (within-gene range 3–6): SND1-IT1, LRRC4, MIR593, MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2.
- chr7:132,086,266–159,233,377, 619 genes, copy number 5–8 (broad region; genes not listed).
- chr12:56,041,351–85,342,912, 527 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
